Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LC, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LC-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, Adrenal Cortical 8370/3

Site: Adrenal Gland Cortex @74.0

2/21/13

Procedure: adrenalectomy, splenectomy

Gross description: 8 x 7 x 8cm, 365g

Diagnosis: adrenocortical carcinoma, with bone metastasis

Reference Pathology: none

4/12/13 - New path info indicate metastatic involvement
with Weiss = 4. Malignant.

hu

Process if case proves we'll request
more path. may not ship if
not malignant.

Exon 11 Discrepancy		
IPMNA Discrepancy		
Pre or Malignancy History		
Diagn/Syn/Chronous Primary Noted		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Left

Number of lesions (?)
Two, primary tumor & bony metastasis, tumor obtained from primary site

Tumor size(s)
8x7x8cm

Histologic diagnosis
ACC

Lymph Node Status
X

Pathologic information
T4NxM1

Weiss score
4, derived from path report

Source: NCI Genomic Data Commons file cdf51225-ce13-475f-ba10-1468be8122fb (TCGA-OR-A5LC.CE74A15F-B71A-483D-BDD2-C47413E4DABB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).